Somatic mutation profile of tumor specimen HCM-BROD-0213-C71-02A (aliquot HCM-BROD-0213-C71-02A-11D-A786-36) from HCMI case HCM-BROD-0213-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.3 years (21,286 days).
Specimen HCM-BROD-0213-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e40de7b-cd68-4c28-91f1-0dab5af6c621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0213-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0213-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/047a609a-8341-414a-ac67-43bd14c4ec5e

The open-access MAF lists 89 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 21, Intron 8, Nonsense Mutation 3, Splice Site 3, Splice Region 3, Frame Shift Del 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs104894286, CM981696; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.43360C>T p.R14454* (on ENST00000591111; = p.R7030* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 20/227 reads (9%) | catalogued as rs374140736, CM133385; ClinVar: pathogenic; called by muse, mutect2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 57/134 reads (43%) | catalogued as rs748641243; called by mutect2, varscan2
- ADAMTS13 | c.2686G>A p.V896M | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as rs147732725; called by muse, mutect2, varscan2
- ADCK5 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 150/400 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs782102304; called by muse, varscan2
- CCDC120 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs373973921; called by muse, mutect2, varscan2
- CCDC154 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs574311061; called by muse, mutect2, varscan2
- CD163L1 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768411637; called by muse, mutect2, varscan2
- COBLL1 | c.1763C>T p.S588L (on ENST00000392717; = p.S550L on NM_014900.5) | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs757755954, COSV99528716; called by muse, mutect2, varscan2
- COL19A1 | c.1090G>C p.G364R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59593385; called by muse, mutect2
- COL6A5 | c.3740C>T p.A1247V | Missense Mutation (SNP) | VAF 157/317 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557597562, COSV55209835; called by muse, mutect2, varscan2
- CRYBG1 | c.4694G>T p.C1565F | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs367967419; called by muse, mutect2, varscan2
- DLGAP2 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 134/309 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs773355695, COSV101421011, COSV70099049; called by muse, mutect2, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- EGF | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 200/475 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs780719136; called by muse, mutect2, varscan2
- EIF6 | c.549G>A p.A183= | Splice Region (SNP) | VAF 40/213 reads (19%) | catalogued as rs758817891, COSV99863746, COSV99863902; called by muse, mutect2, varscan2
- FCGBP | c.9388G>A p.A3130T | Missense Mutation (SNP) | VAF 89/808 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs367948062; called by muse, mutect2, varscan2
- FCGBP | c.5785G>A p.A1929T | Missense Mutation (SNP) | VAF 268/448 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1273367609; called by mutect2, varscan2
- IGF2BP2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs759323959, COSV60485073; called by muse, mutect2, varscan2
- IL17RE | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs992398278; called by muse, mutect2, varscan2
- JAG2 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 130/296 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59311851; called by muse, mutect2, varscan2
- MYH3 | c.4801G>A p.A1601T | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs764578014, COSV56860342; called by muse, mutect2, varscan2
- PRR23A | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 130/291 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1420782431; called by muse, mutect2, varscan2
- SCN5A | c.5795C>T p.A1932V (on ENST00000333535 / NM_198056.3; = p.A1931V on NM_000335.5) | Missense Mutation (SNP) | VAF 98/251 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs371194826; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC1A6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs996260256, COSV55667680; called by muse, mutect2, varscan2
- SMC4 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as rs1197088993; called by muse, mutect2, varscan2
- TRPA1 | c.1207A>G p.K403E | Missense Mutation (SNP) | VAF 175/380 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51574899; called by muse, mutect2, varscan2
- ZNF280C | c.2092G>A p.G698S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs778134912; called by muse, mutect2, varscan2
- ANKRD31 | c.2143C>T p.H715Y | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.278del p.T93Kfs*36 | Frame Shift Del (DEL) | VAF 52/141 reads (37%) | called by mutect2, pindel, varscan2
- ARMH1 | c.1209A>T p.K403N | Missense Mutation (SNP) | VAF 171/339 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH9 | c.1631-1G>C p.X544_splice | Splice Site (SNP) | VAF 80/160 reads (50%) | called by muse, mutect2, varscan2
- CTAG2 | c.267G>A p.E89= | Splice Region (SNP) | VAF 134/247 reads (54%) | called by muse, mutect2, varscan2
- GRK1 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSBP1L1 | c.93del p.L32* | Frame Shift Del (DEL) | VAF 46/178 reads (26%) | called by mutect2, pindel, varscan2
- IGSF1 | c.1044T>A p.D348E | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- IL26 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- KIAA1109 | c.12587G>T p.G4196V | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIMA1 | c.158A>G p.K53R | Missense Mutation (SNP) | VAF 138/294 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MROH5 | c.3860A>T p.E1287V | Missense Mutation (SNP) | VAF 88/205 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR2F1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PCDH7 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 125/255 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PNCK | c.667C>T p.Q223* (on ENST00000340888 / NM_001366975.1; = p.Q306* on NM_001039582.3) | Nonsense Mutation (SNP) | VAF 106/225 reads (47%) | called by muse, mutect2, varscan2
- PRRC2C | c.298G>C p.E100Q (on ENST00000367742; = p.E98Q on NM_015172.4) | Missense Mutation (SNP) | VAF 113/239 reads (47%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PTPN23 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 182/389 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SH2B1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SNRK | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SORBS1 | c.2418_2429+8del p.X806_splice (on ENST00000361941 / NM_001034954.2; = p.X456_splice on NM_006434.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 21/171 reads (12%) | called by mutect2, pindel
- SPATA13 | c.1498G>A p.G500S | Missense Mutation (SNP) | VAF 98/241 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SPATA31E1 | c.1544C>G p.P515R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ST6GAL2 | c.309A>C p.Q103H | Missense Mutation (SNP) | VAF 79/192 reads (41%) | PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SV2A | c.666G>C p.W222C | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TECRL | c.436-2A>T p.X146_splice | Splice Site (SNP) | VAF 67/163 reads (41%) | called by muse, mutect2, varscan2
- TMF1 | c.3245C>G p.T1082S | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TTN | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 190/399 reads (48%) | PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TUBG1 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB40 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 132/340 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZMAT1 | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 113/206 reads (55%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.1200G>A p.P400= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs548446171; called by muse, mutect2, varscan2
- ATAD2B | c.126G>A p.R42= | Silent (SNP) | VAF 155/377 reads (41%) | called by muse, mutect2, varscan2
- BCL6 | c.201C>T p.C67= | Silent (SNP) | VAF 11/267 reads (4%) | called by muse, mutect2
- BCOR | c.2598C>T p.H866= | Silent (SNP) | VAF 135/254 reads (53%) | catalogued as rs778532489; ClinVar: benign; called by muse, mutect2, varscan2
- DCAF12L2 | c.1002G>A p.P334= | Silent (SNP) | VAF 96/237 reads (41%) | catalogued as rs745642585, COSV63580297; called by muse, mutect2, varscan2
- DMXL1 | c.7488A>G p.Q2496= | Silent (SNP) | VAF 131/305 reads (43%) | catalogued as rs747836417; called by muse, mutect2, varscan2
- EOMES | c.768G>A p.G256= | Silent (SNP) | VAF 279/586 reads (48%) | called by muse, mutect2, varscan2
- ERICH3 | c.2433G>A p.A811= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs541437663; called by muse, mutect2, varscan2
- ESX1 | c.996C>T p.P332= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1473684418; called by muse, varscan2
- ITPR3 | c.7509C>A p.I2503= | Silent (SNP) | VAF 70/209 reads (33%) | catalogued as COSV100951969; called by muse, mutect2, varscan2
- KCND1 | c.1125C>T p.Y375= | Silent (SNP) | VAF 78/117 reads (67%) | catalogued as rs149356987, COSV99502112; called by muse, mutect2, varscan2
- MMS19 | c.3039G>A p.K1013= | Silent (SNP) | VAF 92/155 reads (59%) | called by muse, mutect2, varscan2
- OR14C36 | c.938A>G p.*313= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs774461968; called by muse, mutect2, varscan2
- PLCD3 | c.1626C>T p.T542= | Silent (SNP) | VAF 48/130 reads (37%) | called by muse, mutect2, varscan2
- PRKG2 | c.1029A>C p.P343= | Silent (SNP) | VAF 98/225 reads (44%) | called by muse, mutect2, varscan2
- SERPINA1 | c.1158C>T p.P386= | Silent (SNP) | VAF 112/246 reads (46%) | catalogued as rs143329723, CD890162; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLCO4A1 | c.1317G>A p.L439= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2, varscan2
- SP100 | c.2151C>T p.C717= | Silent (SNP) | VAF 106/226 reads (47%) | catalogued as rs370133777; called by muse, mutect2, varscan2
- TMEM74B | c.354G>A p.P118= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as rs139413230; called by muse, mutect2, varscan2
- TRIM46 | c.1530C>T p.N510= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as rs780840567; called by muse, mutect2, varscan2
- ZNF683 | c.894C>T p.V298= | Silent (SNP) | VAF 26/455 reads (6%) | called by muse, mutect2
- AC139769.1 | n.214-4031G>T | Intron (SNP) | VAF 284/991 reads (29%) | called by muse, mutect2, varscan2
- ACSM3 | c.639-901C>A | Intron (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.858+78G>A | Intron (SNP) | VAF 116/326 reads (36%) | called by muse, mutect2, varscan2
- BOLL | c.553-1571T>A | Intron (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- EGFR | c.1881-731C>G | Intron (SNP) | VAF 638/6394 reads (10%) | called by muse, mutect2
- F5 | c.-44C>T | 5'UTR (SNP) | VAF 120/242 reads (50%) | called by muse, mutect2, varscan2
- INSL3 | c.190+918C>T | Intron (SNP) | VAF 41/202 reads (20%) | catalogued as rs1396945981; called by muse, mutect2, varscan2
- POMT2 | c.1892-26G>A | Intron (SNP) | VAF 251/568 reads (44%) | called by muse, mutect2
- RBFOX1 | c.28-185147G>T | Intron (SNP) | VAF 115/243 reads (47%) | catalogued as rs745333470; called by muse, mutect2, varscan2
- SOAT2 | c.*14C>T | 3'UTR (SNP) | VAF 59/126 reads (47%) | catalogued as rs773033784, COSV56859469; called by muse, mutect2, varscan2
